Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A00R, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A00R-01A (Primary Tumor).

ICD-0-3
adenocarcinoma, NOS 8140/3
Site: Cecum C18.0 /w 3/29/11

Sample ID #

Diagnosis:

- 1.: Tumor-free lipomatous atrophic lymph node.
- 2.: Right hemicolectomy specimen with tumor-free resection margins and under inclusion of an ulcerated, malignant, solid tumor in the cecum, conforming to the type of a poorly differentiated adenocarcinoma, with infiltration of the lamina muscularis propria and without regional lymph node metastases (G3, pT2 L0 V0 R0 pN0 0/27). Additional immunohistological investigations are being conducted due to the histological peculiarities of the tumor. A follow-up report on this will be submitted at a later date.

Follow-up report:

From an immunohistological perspective, the tumor cells were positive for broad-spectrum cytokeratins. Large numbers of CD3-positive and CD20-negative or T-lymphocytes are also interspersed.

Based on the histology and immunohistology, this is thus a poorly differentiated colorectal adenocarcinoma, or cecum carcinoma, with a dense lymphocytic stromal infiltrate.

The poor tumor differentiation and the dense lymphocytic inflammatory infiltration may be indicators of the presence of a microsatellite unstable (possibly HNPCC-associated) colorectal carcinoma.

Source: NCI Genomic Data Commons file 33104831-3499-4da1-80ba-88e4a4b22c31 (TCGA-AA-A00R.A4E3D45C-6471-4FBA-BC47-AF0FDC01E417.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).